Somatic mutation profile of tumor specimen TCGA-DJ-A1QL-01A (aliquot TCGA-DJ-A1QL-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QL, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 70.4 years (25,713 days).
Specimen TCGA-DJ-A1QL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5212ff8d-dbc8-4083-9bde-59332094b999.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QL-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QL-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1978b169-a493-463e-b5d9-819b85ad24a4

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10B | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59163688; called by muse, mutect2, varscan2
- C9orf72 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.909); catalogued as rs767044830, COSV66155105; called by muse, mutect2, varscan2
- GALNT18 | c.670C>A p.R224S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57146090, COSV57156889; called by muse, mutect2, varscan2
- HS3ST4 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs762212461, COSV58804994; called by muse, mutect2, varscan2
- PPFIA4 | c.350A>T p.H117L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55320725; called by muse, mutect2, varscan2
- SIDT1 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53506546, COSV53507568; called by muse, mutect2, varscan2
- SLITRK3 | c.1707C>G p.D569E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs764746656, COSV53852970; called by muse, mutect2, varscan2
- TAF1L | c.4123C>T p.R1375W | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs533523762, COSV54268511; called by muse, mutect2, varscan2
- USP28 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as rs868794164, COSV50162246; called by muse, mutect2, varscan2
- WRN | c.3533T>C p.L1178P | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53306706; called by muse, mutect2, varscan2
- PPM1D | c.1434_1455del p.C478* | Frame Shift Del (DEL) | VAF 12/144 reads (8%) | called by mutect2, pindel
- SLC22A11 | c.414C>T p.S138= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV57252106; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500808 A>T | 5'Flank (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
